Somatic mutation profile of tumor specimen 0DK84E from CCDI case PBBUSJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (61 days).
Specimen 0DK84E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a28b4687-fee9-4362-908c-86dac4d449d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK83Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b899ff02-4916-4aa2-aafc-2c85e1e0baf8

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAP1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs1489923285, COSV61506097; called by muse, mutect2
- SPTBN2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1478933802, COSV100020211; ClinVar: likely benign; called by muse, mutect2
- DST | c.21153G>T p.L7051F (on ENST00000361203 / NM_001374722.1; = p.L4748F on NM_015548.5) | Missense Mutation (SNP) | VAF 32/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OFD1 | c.388G>T p.G130* | Nonsense Mutation (SNP) | VAF 201/226 reads (89%) | called by muse, mutect2, varscan2
- ZNF131 | c.1850C>T p.T617I (on ENST00000509156 / NM_001330707.2; = p.T583I on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRFAP1 | c.84G>T p.L28= | Silent (SNP) | VAF 26/838 reads (3%) | catalogued as rs997706856; called by muse, mutect2
- TTN | c.26130C>T p.P8710= (on ENST00000591111; = p.P7783= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/327 reads (42%) | catalogued as rs1310499862; called by muse, mutect2, varscan2
- GTF3C3 | c.1831+11C>G | Intron (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2, varscan2
